Gene-level copy-number profile of tumor specimen MP2PRT-PATIFC-TTR1-A from MP2PRT case MP2PRT-PATIFC, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.1 years (1,854 days).
Specimen MP2PRT-PATIFC-TTR1-A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f5f4b7fe-214c-40b6-b668-e9464b9ead22.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATIFC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/44823bf8-7da1-4cc3-849a-154502b944ee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,550; copy number 2: 43,268; copy number 3: 12,523; copy number 4: 1,025; copy number 5: 25.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,866,658–6,880,626, 2 genes: OR7E136P, OR7E59P.
- chr7:56,991,888–57,020,273, 2 genes: TNRC18P3, SLC29A4P1.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 5: CFHR3.
- chr2:15,564,170–16,555,564, 24 genes, copy number 5 (within-gene range 3–5): AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.4, AC010880.1, AC104623.1, AC104623.2.

Autosomal genes at a single copy (total copy number 1): 1,542. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
